Somatic mutation profile of tumor specimen TCGA-29-1784-01A (aliquot TCGA-29-1784-01A-02W-0633-09) from TCGA case TCGA-29-1784, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.3 years (20,210 days).
Specimen TCGA-29-1784-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 151c2b95-ed49-40af-90f8-d70363c4cc03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1784-10A (Blood Derived Normal), aliquot TCGA-29-1784-10A-01W-0634-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1d11f67-ee43-4bed-afea-51896c7aa2f4

The open-access MAF lists 133 somatic variants for this specimen: 105 protein-altering or splice-affecting, 21 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 21, Nonsense Mutation 6, RNA 5, Frame Shift Del 3, Splice Site 3, Splice Region 2, Intron 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376-2A>G p.X126_splice | Splice Site (SNP) | VAF 31/56 reads (55%) | hotspot (GDC flag); catalogued as rs786202799, CS114003, COSV52689235, COSV52691326, COSV53121815, COSV53758902; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACADM | c.204T>A p.D68E | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63720384; called by muse, mutect2, varscan2
- ACTRT1 | c.1103C>A p.T368K | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV64419351; called by muse, mutect2, varscan2
- ADAM11 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52346253, COSV52347047; called by muse, mutect2, varscan2
- AKAP9 | c.11229G>C p.K3743N (on ENST00000359028; = p.K3719N on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104417035, COSV62345861; called by muse, varscan2
- AMFR | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51921224; called by muse, mutect2, varscan2
- AOAH | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1175693835, COSV99331817; called by muse, mutect2
- ARHGAP28 | c.1036C>G p.L346V (on ENST00000383472 / NM_001366230.1; = p.L187V on NM_001010000.3) | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV99149352; called by muse, mutect2
- ARHGEF11 | c.3444G>T p.E1148D | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV59354395; called by muse, mutect2, varscan2
- ASAP3 | c.2190C>G p.N730K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV60874616; called by muse, mutect2, varscan2
- AZI2 | c.694A>G p.N232D | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV55423859; called by muse, mutect2, varscan2
- BFSP1 | c.546A>C p.E182D | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.802); catalogued as COSV100925312, COSV64900278; called by muse, mutect2, varscan2
- BTN3A3 | c.1594C>G p.L532V | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV55071902; called by muse, mutect2, varscan2
- CASZ1 | c.2852C>T p.S951L | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.242); catalogued as COSV59732548, COSV59734201; called by muse, mutect2
- CDC27 | c.2126G>C p.R709T | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV50383602; called by muse, mutect2, varscan2
- CHD9 | c.437A>T p.H146L | Missense Mutation (SNP) | VAF 59/107 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV68298124; called by muse, mutect2, varscan2
- COL14A1 | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as rs755318491, COSV52854154; called by muse, mutect2, varscan2
- CSF2RA | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.174); catalogued as COSV62624596; called by muse, mutect2, varscan2
- CSMD3 | c.10538C>A p.P3513H (on ENST00000297405 / NM_001363185.1; = p.P3344H on NM_052900.3) | Missense Mutation (SNP) | VAF 73/182 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52111903, COSV52176828; called by muse, mutect2, varscan2
- CYLC2 | c.566A>G p.N189S | Missense Mutation (SNP) | VAF 25/277 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749657927, COSV100872410; called by muse, mutect2
- DCBLD2 | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs200547215; called by muse, mutect2, varscan2
- DHCR24 | c.1161G>A p.M387I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.78); catalogued as COSV64874601; called by muse, mutect2, varscan2
- DLG3 | c.2046G>T p.M682I (on ENST00000374360 / NM_021120.4; = p.M377I on NM_020730.3) | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52085742, COSV99529376; called by muse, mutect2
- DNAH17 | c.10874A>C p.H3625P | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV67754127; called by muse, mutect2, varscan2
- DOCK4 | c.2586C>G p.I862M | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV70236641; called by muse, mutect2, varscan2
- DPY19L2 | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100193156; called by muse, mutect2
- E2F5 | c.908T>C p.I303T | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as rs889979856, COSV56274757; called by muse, mutect2, varscan2
- EHMT2 | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as COSV64993829; called by muse, varscan2
- ERBB3 | c.1472G>C p.R491T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV57253062; called by muse, mutect2, varscan2
- FAM126A | c.300C>A p.C100* | Nonsense Mutation (SNP) | VAF 40/136 reads (29%) | catalogued as COSV69017093; called by muse, mutect2, varscan2
- FAM83B | c.1377G>T p.R459S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60921971, COSV60925896; called by muse, mutect2, varscan2
- FOLR1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56616076; called by muse, mutect2, varscan2
- GANAB | c.1600G>C p.A534P | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV60464549; called by muse, mutect2, varscan2
- GJB3 | c.280C>A p.H94N | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796807027, COSV64904635; called by muse, mutect2
- GLDN | c.1639A>G p.T547A | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1341740510, COSV59090036; called by muse, mutect2, varscan2
- GNL2 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1445775596, COSV56169850; called by muse, mutect2, varscan2
- GPAT2 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.077); catalogued as rs374197811; called by muse, mutect2, varscan2
- GTSF1L | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV65932570; called by muse, mutect2, varscan2
- HAT1 | c.605T>G p.F202C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51362524; called by muse, mutect2, varscan2
- HERC2 | c.11380A>T p.R3794W | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV99872448; called by muse, mutect2
- HIVEP3 | c.2097G>T p.M699I | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV56015289; called by muse, mutect2, varscan2
- HSPA1L | c.533C>G p.P178R | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65149033; called by muse, mutect2, varscan2
- HTR3D | c.500C>A p.S167Y (on ENST00000382489 / NM_001163646.2; = p.S32Y on NM_182537.3) | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.629); catalogued as COSV61913963, COSV61914022; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1810C>T p.P604S | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.003); catalogued as COSV61156904; called by muse, mutect2, varscan2
- KCNH1 | c.2597C>A p.T866K (on ENST00000271751 / NM_172362.3; = p.T839K on NM_002238.4) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV55081023; called by muse, mutect2, varscan2
- KCNV1 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52086048; called by muse, mutect2, varscan2
- KLHL8 | c.1211G>T p.R404L | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56746744, COSV56747770; called by muse, mutect2, varscan2
- LCTL | c.385A>C p.K129Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as COSV58422046; called by muse, mutect2, varscan2
- LILRA1 | c.357A>T p.T119= | Splice Region (SNP) | VAF 4/38 reads (11%) | catalogued as COSV52180651; called by muse, varscan2
- LPA | c.2870C>G p.T957R | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as rs777900381, COSV100306552; called by muse, mutect2
- MAP3K19 | c.2077T>A p.S693T | Missense Mutation (SNP) | VAF 91/197 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.12); catalogued as COSV59638787; called by muse, mutect2, varscan2
- MCF2 | c.1130T>A p.I377K | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as COSV58484688; called by muse, mutect2, varscan2
- MCTP2 | c.1671C>A p.N557K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV59144040; called by muse, mutect2, varscan2
- MOB1B | c.356T>C p.M119T | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58673812; called by muse, mutect2, varscan2
- MPL | c.909G>A p.W303* | Nonsense Mutation (SNP) | VAF 27/372 reads (7%) | catalogued as COSV100991511; called by muse, mutect2
- MYH1 | c.5204A>G p.E1735G | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56848196; called by muse, mutect2, varscan2
- MYH4 | c.3076A>T p.K1026* | Nonsense Mutation (SNP) | VAF 32/197 reads (16%) | catalogued as COSV55117986; called by muse, mutect2, varscan2
- NBPF10 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 49/326 reads (15%) | catalogued as rs782117009, COSV61670355; called by muse, mutect2, varscan2
- NEURL1 | c.326A>T p.K109M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63914470; called by muse, varscan2
- NOXRED1 | c.1073C>A p.S358Y | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as COSV53629322; called by muse, mutect2, varscan2
- NPSR1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 13/116 reads (11%) | catalogued as COSV62197011, COSV62200166; called by muse, mutect2, varscan2
- NR1D2 | c.953T>C p.L318P | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV56991876; called by muse, mutect2, varscan2
- NR1H4 | c.35T>A p.I12N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV51851825; called by muse, mutect2, varscan2
- OR2F2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 246/514 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV68832778; called by muse, mutect2, varscan2
- PAPPA2 | c.767C>G p.S256C | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as COSV62777965; called by muse, mutect2, varscan2
- PCDH19 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55262598; called by muse, mutect2, varscan2
- PDE6A | c.1113G>C p.Q371H | Missense Mutation (SNP) | VAF 50/560 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV99678102; called by muse, mutect2
- PEX19 | c.532A>G p.I178V | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV100926934; called by muse, mutect2
- POLR1A | c.5065T>A p.S1689T | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.137); catalogued as COSV55692770, COSV99807447; called by muse, mutect2, varscan2
- PPP2R3A | c.3265T>A p.F1089I | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV53863654; called by muse, mutect2, varscan2
- PREX2 | c.4057A>T p.K1353* | Nonsense Mutation (SNP) | VAF 4/62 reads (6%) | catalogued as COSV99906300; called by muse, mutect2
- PRKAG2 | c.1010A>T p.Q337L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV55223301, COSV55229026; called by muse, mutect2, varscan2
- QARS1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.976); catalogued as COSV100069885; called by muse, mutect2
- RP1 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55116454; called by muse, mutect2
- RXYLT1 | c.691A>T p.S231C | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99706797; called by muse, mutect2
- RYR1 | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.842); catalogued as COSV62096973; called by muse, mutect2
- SCRN2 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV99274037; called by muse, mutect2
- SETBP1 | c.3988T>A p.S1330T | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV56321682; called by muse, mutect2, varscan2
- SLC5A1 | c.1834C>G p.L612V | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as COSV56687914; called by muse, mutect2
- SNX1 | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV56038270; called by muse, mutect2, varscan2
- SORBS2 | c.332C>T p.P111L (on ENST00000284776 / NM_021069.5; = p.P157L on NM_003603.6) | Missense Mutation (SNP) | VAF 79/123 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs776231547, COSV52999385; called by muse, mutect2, varscan2
- SREBF2 | c.1118C>G p.A373G | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63331186; called by muse, mutect2, varscan2
- SUSD1 | c.1746G>C p.Q582H | Missense Mutation (SNP) | VAF 69/332 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as COSV62583581; called by muse, mutect2, varscan2
- TCTE1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.325); catalogued as COSV101025319, COSV65255544; called by muse, mutect2
- TENM2 | c.5924C>A p.S1975Y (on ENST00000518659 / NM_001122679.2; = p.S1736Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV69129879; called by muse, mutect2, varscan2
- THOC5 | c.759G>C p.Q253H | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV63798651, COSV63798735; called by muse, mutect2, varscan2
- THSD7A | c.1611C>T p.G537= | Splice Region (SNP) | VAF 13/32 reads (41%) | catalogued as COSV101448611; called by muse, mutect2
- TRIM25 | c.1186G>T p.V396F | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100380958; called by muse, mutect2
- TRIM44 | c.516G>C p.E172D | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.677); catalogued as COSV100195082, COSV54984017; called by muse, mutect2, varscan2
- UHRF1BP1L | c.4072C>T p.H1358Y | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV99691374; called by muse, mutect2
- USP49 | c.1841G>A p.G614E | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51896941; called by muse, mutect2, varscan2
- VGLL3 | c.868G>C p.A290P | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV67352979; called by muse, mutect2, varscan2
- VPS13B | c.5666A>C p.Q1889P | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100661551; called by muse, mutect2
- WBP2 | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV52884540; called by muse, mutect2, varscan2
- XRN2 | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1215542052, COSV65869521; called by muse, varscan2
- ZNF343 | c.1508G>T p.S503I | Missense Mutation (SNP) | VAF 46/409 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.083); catalogued as COSV53853749; called by muse, mutect2, varscan2
- AHNAK2 | c.3569_3576dup p.V1193Hfs*8 | Frame Shift Ins (INS) | VAF 9/44 reads (20%) | called by mutect2, varscan2
- ALDH3A1 | c.1334dup p.S446Efs*51 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- CYBRD1 | c.843del p.Q282Rfs*9 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- DPP8 | c.1585-3_1592del p.X529_splice (on ENST00000341861 / NM_001320875.2; = p.X513_splice on NM_017743.6) | Splice Site (DEL) | VAF 18/47 reads (38%) | called by mutect2, pindel, varscan2
- EPHB2 | c.3070_3091del p.K1024Gfs*52 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- GPR182 | c.946_969delinsCCCA p.N316Pfs*19 | Frame Shift Del (DEL) | VAF 59/163 reads (36%) | called by pindel, varscan2*
- NOTCH2 | c.933T>A p.N311K | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SLC38A6 | c.364-2_380del p.X122_splice | Splice Site (DEL) | VAF 3/38 reads (8%) | called by mutect2, pindel
- TRAV8-1 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- ATP5MF | c.177G>A p.K59= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV52854424; called by muse, mutect2, varscan2
- CLDN2 | c.111T>A p.G37= | Silent (SNP) | VAF 8/198 reads (4%) | catalogued as COSV100390090; called by muse, mutect2
- COL4A6 | c.4665C>T p.P1555= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs1474986430, COSV57866293; called by muse, mutect2, varscan2
- DGKB | c.489G>A p.T163= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs754384796, COSV51781726, COSV51794726; called by muse, mutect2, varscan2
- DPYD | c.2046G>T p.L682= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100928893, COSV64595069; called by muse, mutect2, varscan2
- FN1 | c.3636T>C p.P1212= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV60552501; called by muse, mutect2, varscan2
- H2AC17 | c.261C>A p.A87= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV58152606; called by muse, varscan2
- HAS2 | c.1203T>A p.G401= | Silent (SNP) | VAF 52/569 reads (9%) | catalogued as COSV100391629; called by muse, mutect2
- LSM12 | c.165C>A p.I55= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV53232487; called by muse, mutect2, varscan2
- MMP9 | c.711G>A p.E237= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as COSV63434067; called by muse, mutect2, varscan2
- MRC1 | c.255T>A p.A85= | Silent (SNP) | VAF 81/266 reads (30%) | called by muse, mutect2, varscan2
- OLFM4 | c.1344C>A p.T448= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV54577277; called by muse, mutect2, varscan2
- PAPPA2 | c.2541C>T p.P847= | Silent (SNP) | VAF 58/344 reads (17%) | catalogued as COSV62777970; called by mutect2, varscan2
- PDIA5 | c.501G>A p.K167= | Silent (SNP) | VAF 26/165 reads (16%) | catalogued as rs752115409, COSV60249080; called by muse, mutect2, varscan2
- PNN | c.1978C>T p.L660= | Silent (SNP) | VAF 22/342 reads (6%) | catalogued as COSV99397124; called by muse, mutect2
- PPP1R3A | c.1035T>C p.D345= | Silent (SNP) | VAF 33/153 reads (22%) | catalogued as COSV52882375; called by muse, mutect2, varscan2
- PRUNE2 | c.6615A>G p.V2205= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100944403; called by muse, mutect2
- SPATA7 | c.1614G>C p.V538= | Silent (SNP) | VAF 33/234 reads (14%) | catalogued as COSV50417045; called by muse, mutect2, varscan2
- THRA | c.972A>G p.L324= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV52842903; called by muse, mutect2, varscan2
- VPS13B | c.5667G>A p.Q1889= | Silent (SNP) | VAF 14/246 reads (6%) | catalogued as COSV100661553; called by muse, mutect2
- ZNF438 | c.540A>G p.P180= | Silent (SNP) | VAF 8/123 reads (7%) | catalogued as COSV100061585; called by muse, mutect2
- ABHD12 | c.192-290T>C | Intron (SNP) | VAF 19/45 reads (42%) | catalogued as COSV59285697; called by muse, mutect2, varscan2
- AC244258.1 | n.511C>A | RNA (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- ISCA1P1 | n.235C>T | RNA (SNP) | VAF 110/201 reads (55%) | called by muse, mutect2, varscan2
- NRXN3 | c.989-7450T>C | Intron (SNP) | VAF 36/432 reads (8%) | catalogued as rs1381451678; called by muse, mutect2
- OFCC1 | n.316C>T | RNA (SNP) | VAF 24/205 reads (12%) | catalogued as rs145100001; called by muse, mutect2, varscan2
- OR2W5 | n.778T>C | RNA (SNP) | VAF 35/88 reads (40%) | called by muse, mutect2, varscan2
- ZNF658B | n.1494C>T | RNA (SNP) | VAF 34/274 reads (12%) | catalogued as rs1419064992; called by muse, mutect2
